Somatic mutation profile of tumor specimen TCGA-3N-A9WC-06A (aliquot TCGA-3N-A9WC-06A-11D-A38G-08) from TCGA case TCGA-3N-A9WC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.4 years (31,930 days).
Specimen TCGA-3N-A9WC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1975cab-e73a-49f9-9ce9-9d9181c6ad96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3N-A9WC-10A (Blood Derived Normal), aliquot TCGA-3N-A9WC-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af834040-557f-4378-82aa-a759c8bf2fb7

The open-access MAF lists 2,297 somatic variants for this specimen: 1,436 protein-altering or splice-affecting, 798 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,286, Silent 798, Nonsense Mutation 93, Intron 27, Splice Region 19, RNA 19, Splice Site 19, Frame Shift Del 10, 3'UTR 7, Translation Start Site 6, 5'Flank 6, 5'UTR 4.

Variants (750 of 2,297; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs727504399, COSV51757846; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- ATP7B | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs1555291848, CM105441, COSV99666257; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1840C>T p.H614Y (on ENST00000288602 / NM_001374244.1; = p.H574Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs397516894, COSV56111969, COSV56187614; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- KCNQ3 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1064795142, COSV101195873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.5476C>T p.R1826C (on ENST00000333535 / NM_198056.3; = p.R1825C on NM_000335.5) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs199473635, CM087612; ClinVar: likely pathogenic / uncertain significance / not provided; called by muse, mutect2, varscan2
- A2M | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as rs1173054508, COSV59384139; called by muse, mutect2, varscan2
- A2M | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100588579; called by muse, mutect2, varscan2
- A2ML1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs758305694, COSV100229195, COSV55290676; called by muse, mutect2, varscan2
- A2ML1 | c.3908C>T p.S1303L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV55301170; called by muse, mutect2, varscan2
- AADAT | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs754110103, COSV100528602; called by muse, mutect2, varscan2
- AARS2 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs748288072, COSV99771355; called by muse, mutect2, varscan2
- ABCA10 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99288287; called by muse, mutect2, varscan2
- ABCA12 | c.1516C>T p.P506S (on ENST00000272895 / NM_173076.3; = p.P188S on NM_015657.3) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55947956; called by muse, mutect2, varscan2
- ABCA8 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1037605600, COSV52213519; called by muse, mutect2, varscan2
- ABCB11 | c.266T>G p.V89G | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV99791851; called by muse, mutect2, varscan2
- ABCB5 | c.3272C>T p.S1091F (on ENST00000404938 / NM_001163941.2; = p.S646F on NM_178559.6) | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs267601451, COSV99327954; called by muse, mutect2, varscan2
- ABCC3 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99558949; called by muse, mutect2, varscan2
- ABLIM3 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs764277770, COSV100448222; called by muse, mutect2, varscan2
- AC104389.6 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57963271; called by muse, mutect2, varscan2
- ACBD4 | c.730T>C p.C244R (on ENST00000376955 / NM_001378111.1; = p.V247A on NM_024722.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV100416143; called by muse, mutect2, varscan2
- ACCS | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99772765; called by muse, mutect2, varscan2
- ACSF2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368713564; called by muse, mutect2, varscan2
- ACSM2B | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312518; called by muse, mutect2, varscan2
- ACTN1 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs745859336, COSV51990451; called by muse, mutect2, varscan2
- ACVRL1 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV101187834; called by muse, mutect2, varscan2
- ADAD1 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56647256; called by muse, mutect2, varscan2
- ADAM18 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV55844392; called by muse, mutect2, varscan2
- ADAM22 | c.1787+1G>A p.X596_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV55987635, COSV99716370; called by muse, mutect2, varscan2
- ADAM23 | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100007211; called by muse, mutect2, varscan2
- ADAM29 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164332843, COSV63669099; called by muse, mutect2, varscan2
- ADAMDEC1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56476564; called by muse, mutect2, varscan2
- ADAMDEC1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1351755384, COSV99835912; called by muse, mutect2, varscan2
- ADAMTS14 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763213695, COSV64599858; called by muse, mutect2, varscan2
- ADAMTS17 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99170483; called by muse, mutect2, varscan2
- ADAMTS18 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99271943; called by muse, mutect2, varscan2
- ADCY1 | c.3027G>A p.M1009I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99811710; called by muse, mutect2, varscan2
- ADD2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1256425970, COSV100035222; called by muse, mutect2, varscan2
- ADGRB3 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); catalogued as rs768222706, COSV101000259; called by muse, mutect2, varscan2
- ADGRB3 | c.3212G>A p.G1071D | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs766550347, COSV99484449; called by muse, varscan2
- ADGRB3 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV53243343, COSV53250175, COSV53259502; called by muse, varscan2
- ADGRF4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs771530266, COSV51951749, COSV51955542; called by muse, mutect2, varscan2
- ADGRF5 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99345272; called by muse, mutect2, varscan2
- ADGRG7 | c.1677G>A p.M559I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs745983793, COSV99840828; called by muse, mutect2, varscan2
- ADGRL2 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.066); catalogued as rs764807610, COSV99588073; called by muse, mutect2, varscan2
- ADGRL4 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100875811; called by muse, mutect2, varscan2
- ADGRV1 | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1435003118, COSV101315709; called by muse, mutect2, varscan2
- ADIPOR1 | c.226G>C p.A76P | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100579462; called by muse, mutect2, varscan2
- AGTR2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903549; called by muse, mutect2, varscan2
- AIRE | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99381064; called by muse, mutect2, varscan2
- AK5 | c.272C>T p.P91L (on ENST00000354567 / NM_174858.3; = p.P65L on NM_012093.4) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100481417, COSV100481537; called by muse, mutect2, varscan2
- AK9 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100393480; called by muse, mutect2, varscan2
- AKAP6 | c.5516C>T p.P1839L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV99799806, COSV99799876; called by muse, mutect2, varscan2
- AL121899.2 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67351449; called by muse, mutect2, varscan2
- ALB | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV55740500, COSV99891139; called by muse, mutect2, varscan2
- ALCAM | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV100064559, COSV60247134; called by muse, mutect2, varscan2
- ALG6 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99673094; called by muse, mutect2, varscan2
- ALMS1 | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs565214018, COSV100041887; called by muse, mutect2, varscan2
- ALOX12 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52349038; called by muse, mutect2, varscan2
- ALPK2 | c.2958G>A p.W986* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100864264; called by mutect2, varscan2
- ALPK2 | c.2957G>A p.W986* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100864265; called by muse, mutect2, varscan2
- AMBN | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs778971384, COSV59826656; called by muse, mutect2, varscan2
- AMER3 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs758673608, COSV58466746; called by muse, mutect2, varscan2
- AMIGO2 | c.833G>A p.S278N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99873548; called by muse, mutect2, varscan2
- ANAPC1 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100594621; called by muse, mutect2, varscan2
- ANK2 | c.11522C>T p.P3841L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); catalogued as rs767769233, COSV52174340; called by muse, mutect2, varscan2
- ANK3 | c.7537G>A p.E2513K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV55058315; called by muse, mutect2, varscan2
- ANK3 | c.6421C>T p.P2141S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs747941101, COSV99779270; called by muse, mutect2, varscan2
- ANK3 | c.5675C>T p.P1892L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV99779272; called by muse, mutect2, varscan2
- ANKRD17 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs748344334, COSV100428861; called by muse, mutect2, varscan2
- ANO2 | c.2840T>C p.L947P (on ENST00000356134 / NM_001278597.3; = p.L951P on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100500383; called by muse, mutect2, varscan2
- ANO4 | c.603G>A p.R201= (on ENST00000392977 / NM_001286615.2; = p.R166= on NM_178826.4) | Splice Region (SNP) | VAF 77/288 reads (27%) | catalogued as COSV54603836; called by muse, mutect2, varscan2
- ANO4 | c.2736C>A p.D912E (on ENST00000392977 / NM_001286615.2; = p.D877E on NM_178826.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); catalogued as COSV100152526; called by muse, mutect2, varscan2
- AOX1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV65980055; called by muse, mutect2, varscan2
- AP3B2 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV99916262; called by muse, mutect2
- APBA1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454451021, COSV55237715, COSV99596318; called by muse, mutect2, varscan2
- APC | c.4264G>A p.D1422N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57328281, COSV57398043; called by muse, mutect2, varscan2
- APCDD1L | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100953964; called by muse, mutect2, varscan2
- APCS | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99661246; called by muse, mutect2, varscan2
- APOB | c.12068A>G p.N4023S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV99264797; called by muse, mutect2, varscan2
- APOB | c.5543C>T p.S1848L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV51936444; called by muse, mutect2, varscan2
- ARAP2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV58281921; called by muse, mutect2, varscan2
- ARFIP1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100617099; called by muse, mutect2, varscan2
- ARHGAP27 | c.1129C>T p.P377S (on ENST00000428638 / NM_001282290.1; = p.P36S on NM_199282.3) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV100976478; called by muse, mutect2, varscan2
- ARHGAP6 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100272638; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- ARMCX1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV100863173; called by muse, mutect2, varscan2
- ARRDC3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99475229, COSV99475257; called by muse, mutect2, varscan2
- ASCC2 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs529000348, COSV100316157; called by muse, mutect2, varscan2
- ASH1L | c.8078A>T p.H2693L (on ENST00000368346 / NM_001366177.2; = p.H2688L on NM_018489.3) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100853295; called by muse, mutect2, varscan2
- ASIC2 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751735036, COSV99859730; called by muse, mutect2, varscan2
- ASIC3 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876781; called by muse, mutect2, varscan2
- ASXL2 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55470167, COSV99710768; called by muse, mutect2, varscan2
- ASXL3 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV99324196; called by muse, mutect2, varscan2
- ASZ1 | c.974A>T p.K325I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV99497888; called by muse, mutect2, varscan2
- ATAD2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV99784386; called by muse, mutect2, varscan2
- ATP10D | c.3308G>A p.G1103E | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99905433; called by muse, mutect2, varscan2
- ATP12A | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566077545, COSV54515540; called by muse, mutect2, varscan2
- ATP13A5 | c.3536C>T p.S1179L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs1439026092, COSV99290624; called by muse, mutect2, varscan2
- ATP1A4 | c.491A>T p.K164M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100927493; called by muse, mutect2, varscan2
- ATR | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.182); catalogued as COSV100637960; called by muse, mutect2, varscan2
- ATXN7 | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99894142; called by muse, mutect2, varscan2
- ATXN7 | c.1361+1G>A p.X454_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99894144; called by muse, mutect2, varscan2
- AWAT2 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99339596; called by muse, varscan2
- BAHCC1 | c.4424C>T p.S1475L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV100311417; called by muse, mutect2
- BCAM | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99538632; called by muse, mutect2, varscan2
- BDKRB2 | c.620A>T p.N207I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100021025; called by muse, varscan2
- BEND2 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101191920; called by muse, mutect2, varscan2
- BEND7 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100346550; called by muse, mutect2, varscan2
- BEST2 | c.482-1G>A p.X161_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99244338; called by muse, mutect2
- BICRA | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV101194267; called by muse, mutect2, varscan2
- BMP5 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.033); catalogued as rs770256367, COSV100895862; called by muse, mutect2, varscan2
- BMP6 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV99306657; called by muse, mutect2, varscan2
- BPIFA2 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99487827; called by muse, mutect2, varscan2
- BPIFB4 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64952347; called by muse, mutect2, varscan2
- BRD1 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99349515; called by muse, mutect2, varscan2
- BRINP3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.026); catalogued as COSV100818610; called by muse, mutect2, varscan2
- BTBD1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.196); catalogued as COSV99915380; called by muse, mutect2, varscan2
- BTBD11 | c.2096G>A p.G699E (on ENST00000280758 / NM_001018072.2; = p.G236E on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603282, COSV55021617; called by muse, mutect2, varscan2
- BTBD9 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100021445; called by muse, mutect2, varscan2
- BTN1A1 | c.1181G>A p.W394* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | catalogued as COSV99764296; called by muse, mutect2, varscan2
- BTN2A1 | c.375T>G p.C125W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438493, COSV57005419; called by muse, mutect2, varscan2
- BTN2A2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV100760334; called by muse, mutect2, varscan2
- BTNL2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV100896034; called by muse, mutect2, varscan2
- BTNL3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1352498373, COSV100732194; called by muse, mutect2, varscan2
- C10orf71 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as rs767721099, COSV60515039; called by muse, mutect2, varscan2
- C12orf40 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.134); catalogued as COSV61132770; called by muse, mutect2
- C12orf43 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV99982422; called by muse, mutect2, varscan2
- C16orf70 | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99531252; called by muse, mutect2, varscan2
- C16orf78 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100147639; called by muse, mutect2, varscan2
- C17orf98 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221061151; called by muse, mutect2, varscan2
- C19orf57 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100694668; called by muse, mutect2, varscan2
- C1QC | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM142890, COSV101009445; called by muse, mutect2, varscan2
- C1orf131 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.656); catalogued as COSV100009654; called by muse, mutect2, varscan2
- C1orf94 | c.1552G>A p.G518R (on ENST00000488417 / NM_001134734.2; = p.G328R on NM_032884.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs768202401, COSV100974799; called by muse, mutect2, varscan2
- C2orf16 | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs760057930, COSV100820733; called by muse, mutect2
- C4BPA | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891179; called by muse, mutect2, varscan2
- C5orf15 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV99198307; called by muse, mutect2, varscan2
- C6 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as COSV99666847; called by muse, mutect2, varscan2
- C8A | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63484714; called by muse, mutect2, varscan2
- C8A | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV63483118; called by muse, mutect2, varscan2
- C8orf34 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.24); catalogued as rs867134366, COSV100297876; called by muse, mutect2, varscan2
- CA1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56277212; called by muse, mutect2, varscan2
- CABP5 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV53153181, COSV99506372; called by muse, mutect2, varscan2
- CACHD1 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as COSV51553370; called by muse, mutect2, varscan2
- CACNA1C | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205750, COSV100215463, COSV59694566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.3250C>T p.P1084S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100217497; called by muse, mutect2, varscan2
- CACNA1E | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV100701831; called by muse, mutect2, varscan2
- CACNA1G | c.6187C>T p.P2063S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1175197140, COSV100661585; called by muse, mutect2, varscan2
- CACNA1I | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762395905, COSV100359813, COSV100361482; called by muse, mutect2
- CACNA1S | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62939455; called by muse, mutect2, varscan2
- CACNA2D2 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56562084; called by muse, mutect2, varscan2
- CADM2 | c.571C>T p.R191* (on ENST00000407528 / NM_001167674.2; = p.R193* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs1299583755, COSV67359184; called by muse, mutect2, varscan2
- CADM3 | c.665C>T p.S222F (on ENST00000368125 / NM_001127173.3; = p.S256F on NM_021189.5) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.608); catalogued as rs867065366, COSV63683495; called by muse, mutect2, varscan2
- CARD11 | c.1592G>A p.G531D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100829122; called by muse, mutect2, varscan2
- CARD11 | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100829123; called by muse, mutect2, varscan2
- CATSPERD | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs757837954, COSV101062597, COSV67534240; called by muse, mutect2, varscan2
- CBLC | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs745556828, COSV54323156; called by muse, mutect2, varscan2
- CBLL1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs764776585, COSV56028078; called by muse, mutect2, varscan2
- CBY2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100137550; called by muse, mutect2, varscan2
- CC2D1B | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1189349300, COSV99429879; called by muse, mutect2, varscan2
- CCAR1 | c.292T>C p.L98= | Splice Region (SNP) | VAF 35/118 reads (30%) | catalogued as COSV56270150; called by muse, mutect2, varscan2
- CCDC124 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101506500, COSV71490395; called by muse, mutect2, varscan2
- CCDC144A | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs562861000, COSV100138468; called by muse, mutect2, varscan2
- CCDC150 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs202212006, COSV99776751; called by muse, mutect2, varscan2
- CCDC180 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.155); catalogued as COSV63834066; called by muse, mutect2, varscan2
- CCDC57 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV66433512; called by muse, mutect2, varscan2
- CCDC88C | c.2702C>T p.T901I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101105448; called by muse, mutect2, varscan2
- CCKAR | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV55161143; called by muse, mutect2, varscan2
- CCN1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as COSV101486123; called by muse, mutect2, varscan2
- CCNT1 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99980653; called by muse, mutect2, varscan2
- CCNT1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99980657; called by muse, mutect2, varscan2
- CCNT1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs768603622, COSV99980659; called by muse, mutect2, varscan2
- CCNT2 | c.2081C>T p.T694I (on ENST00000264157 / NM_058241.3; = p.D660= on NM_001241.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99750455; called by muse, mutect2, varscan2
- CCR8 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100413051; called by muse, mutect2, varscan2
- CD1A | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1012151702, COSV99192272; called by muse, mutect2, varscan2
- CD1B | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV100939196; called by muse, mutect2, varscan2
- CD22 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50071836; called by muse, mutect2, varscan2
- CD300A | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 41/79 reads (52%) | catalogued as COSV100177880; called by muse, mutect2, varscan2
- CD300E | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs1380799899, COSV100151247; called by muse, mutect2, varscan2
- CD300LG | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV53225399, COSV53225599; called by muse, mutect2, varscan2
- CD6 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57835968; called by muse, mutect2, varscan2
- CDC25A | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs142106531; called by muse, mutect2, varscan2
- CDCP1 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV99943945; called by muse, mutect2, varscan2
- CDCP1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs1244269384, COSV56103871; called by muse, mutect2, varscan2
- CDH10 | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100050822, COSV52591531; called by muse, mutect2, varscan2
- CDH12 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs765635488, COSV66386124; called by muse, mutect2, varscan2
- CDH4 | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100848650; called by muse, mutect2, varscan2
- CDH9 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1490543922, COSV50470115; called by muse, mutect2, varscan2
- CDH9 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV50295740; called by muse, mutect2, varscan2
- CDK18 | c.541G>A p.G181R (on ENST00000506784 / NM_212503.3; = p.G151R on NM_002596.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778624604, COSV100773979; called by muse, mutect2, varscan2
- CDK3 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100044289; called by muse, mutect2, varscan2
- CDON | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99701069; called by muse, mutect2, varscan2
- CEACAM5 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.556); catalogued as COSV55755444; called by muse, mutect2, varscan2
- CEP112 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV101210681; called by muse, mutect2
- CEP126 | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV99680873; called by muse, mutect2, varscan2
- CFAP221 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs771543800, COSV99732217; called by muse, mutect2, varscan2
- CFAP221 | c.1349T>A p.I450N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.187); catalogued as COSV99732219; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2
- CFAP54 | c.7990C>T p.H2664Y | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100733066; called by muse, mutect2, varscan2
- CFAP65 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100444907; called by muse, mutect2, varscan2
- CFAP70 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV100160393; called by muse, mutect2, varscan2
- CFH | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV100661370; called by muse, mutect2
- CFH | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs754500480, COSV66406878; called by muse, mutect2, varscan2
- CFTR | c.3848G>A p.R1283K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs77902683, CM920189, CM940278, COSV99135077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGA | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100851676; called by muse, mutect2
- CGN | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434480209, COSV99642145; called by muse, mutect2, varscan2
- CHD5 | c.1644G>A p.M548I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99313167; called by muse, mutect2, varscan2
- CHGB | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs567433214, COSV66761787; called by muse, mutect2, varscan2
- CHP1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100587033; called by muse, mutect2, varscan2
- CHP2 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100270103, COSV100270311; called by muse, mutect2, varscan2
- CIDEC | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV100396600; called by muse, mutect2
- CIDEC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs762188260, COSV100396602; called by muse, mutect2
- CLCN6 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100411771; called by muse, mutect2, varscan2
- CLEC18B | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs1353149485, COSV100375863; called by muse, varscan2
- CLEC4E | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55226819; called by muse, mutect2, varscan2
- CLIP1 | c.3323C>T p.S1108F (on ENST00000620786 / NM_001247997.1; = p.S1097F on NM_002956.2) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56800568; called by muse, mutect2, varscan2
- CLIP4 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100191714; called by muse, mutect2, varscan2
- CMA1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.237); catalogued as COSV99157221; called by muse, mutect2
- CMA1 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.88); catalogued as COSV99157227; called by muse, mutect2
- CMTR2 | c.1675T>G p.L559V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100579079; called by muse, mutect2, varscan2
- CMYA5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV71404281; called by muse, mutect2, varscan2
- CMYA5 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV71404314, COSV71408505; called by muse, mutect2, varscan2
- CMYA5 | c.6112G>A p.E2038K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV71404521; called by muse, mutect2, varscan2
- CNGA3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.398); catalogued as COSV99736456; called by muse, mutect2, varscan2
- CNTN1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100751177; called by muse, mutect2, varscan2
- CNTN6 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268779922, COSV100610451, COSV63181477; called by muse, mutect2, varscan2
- CNTNAP2 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs750079255, COSV62140550; called by muse, mutect2, varscan2
- COL11A1 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62179804; called by muse, mutect2, varscan2
- COL14A1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1270185548, COSV99918006; called by muse, mutect2, varscan2
- COL19A1 | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507613, COSV59568988; called by muse, mutect2, varscan2
- COL21A1 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778185; called by muse, mutect2
- COL22A1 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs574216888, COSV57367618; called by muse, mutect2, varscan2
- COL28A1 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV68082734; called by muse, mutect2, varscan2
- COL4A1 | c.3326-1G>A p.X1109_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV101011049; called by muse, mutect2, varscan2
- COL4A4 | c.3694C>T p.P1232S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100306540; called by muse, mutect2, varscan2
- COL4A4 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237546505, COSV61630230; called by muse, mutect2
- COL4A4 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397058659, CM166128, COSV61634771; called by muse, mutect2, varscan2
- COL4A4 | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV100306542; called by muse, mutect2, varscan2
- COL4A4 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632862; called by muse, mutect2, varscan2
- COL4A6 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as COSV100563820; called by muse, mutect2, varscan2
- COL5A2 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV100880140; called by muse, mutect2, varscan2
- COL6A5 | c.6209T>A p.F2070Y (on ENST00000312481; = p.F2066Y on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99592604; called by muse, mutect2, varscan2
- COL7A1 | c.6689G>A p.G2230E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM096531, COSV100095626; called by muse, mutect2, varscan2
- COL9A2 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV101028438; called by muse, mutect2
- COL9A3 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778892188, COSV58983497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMMD2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.014); catalogued as COSV101519916; called by muse, mutect2, varscan2
- COPG1 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV100135493, COSV59115173; called by muse, mutect2, varscan2
- CPA1 | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145916805; called by muse, mutect2, varscan2
- CPED1 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59997018, COSV60010339; called by muse, mutect2, varscan2
- CPNE5 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99782629, COSV99783272; called by muse, mutect2, varscan2
- CPS1 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV51803862; called by muse, mutect2, varscan2
- CR1 | c.1042C>T p.P348S (on ENST00000367051; = p.P798S on NM_000651.6) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.646); catalogued as rs1473263708, COSV100887499; called by mutect2, varscan2
- CR1L | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687059; called by muse, mutect2
- CR2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV65508854; called by muse, mutect2
- CRB1 | c.3137C>A p.S1046Y | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV100957777; called by muse, mutect2, varscan2
- CRB1 | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs1427358329, COSV66345710; called by muse, mutect2, varscan2
- CREBL2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99963602; called by muse, mutect2
- CRYBB1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV99315919; called by muse, mutect2, varscan2
- CRYBG3 | c.6215C>T p.S2072L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1375628854, COSV99476823; called by muse, mutect2, varscan2
- CSF1 | c.1560G>A p.W520* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100294414; called by muse, mutect2, varscan2
- CSF2RB | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs779590800, COSV99453574; called by muse, mutect2, varscan2
- CSF2RB | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV99453577; called by muse, mutect2, varscan2
- CSH2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs764441972, COSV100400178; called by muse, mutect2, varscan2
- CSMD1 | c.8144G>A p.G2715E (on ENST00000520002; = p.G2714E on NM_033225.6) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59315114; called by muse, varscan2
- CSMD2 | c.10064C>T p.A3355V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs200252481, COSV99588260; called by muse, mutect2, varscan2
- CSMD2 | c.8609C>T p.S2870L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs868166338, COSV53886416, COSV53930983; called by muse, mutect2, varscan2
- CSMD2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as rs771073052, COSV53888042; called by muse, mutect2, varscan2
- CSMD2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169530, COSV53878136; called by muse, mutect2, varscan2
- CSMD3 | c.8500G>A p.G2834R (on ENST00000297405 / NM_001363185.1; = p.G2665R on NM_052900.3) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs765870707, COSV52291510; called by muse, mutect2, varscan2
- CSMD3 | c.8188C>T p.H2730Y | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99822285, COSV99830328; called by muse, mutect2, varscan2
- CYB5RL | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370499414; called by muse, mutect2, varscan2
- CYFIP2 | c.3277C>T p.P1093S (on ENST00000616178 / NM_001291722.2; = p.P1068S on NM_014376.4) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as COSV100557368, COSV59047306; called by muse, mutect2, varscan2
- CYP19A1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV53061144, COSV99547549; called by muse, mutect2, varscan2
- CYP2A13 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.932); catalogued as COSV100386712; called by muse, mutect2, varscan2
- CYP2B6 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437758097, COSV100137429; called by muse, mutect2, varscan2
- CYP2C8 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64878053; called by muse, mutect2, varscan2
- CYP2S1 | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100027406; called by muse, mutect2, varscan2
- CYP4A11 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs370892962, COSV60224540; called by muse, mutect2, varscan2
- CYP4B1 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV54723115, COSV99596965; called by muse, mutect2, varscan2
- CYP4F2 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV99171063; called by muse, mutect2, varscan2
- CYP8B1 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100296097; called by muse, mutect2, varscan2
- CYTH3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100641364; called by muse, mutect2, varscan2
- DAB1 | c.1577C>T p.S526F (on ENST00000371231; = p.S493F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV64692848; called by muse, mutect2, varscan2
- DAB1 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs565043718, COSV100139816; called by muse, mutect2, varscan2
- DACH2 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100912950, COSV100913024; called by muse, mutect2, varscan2
- DAO | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99948506; called by muse, mutect2, varscan2
- DAO | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs866993420, COSV99948509; called by muse, mutect2, varscan2
- DAOA | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV61602449; called by muse, mutect2, varscan2
- DAPP1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV56450291; called by mutect2, varscan2
- DBF4B | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100154419; called by muse, mutect2, varscan2
- DBF4B | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV100154420; called by muse, mutect2, varscan2
- DBH | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1424166493, COSV55040720; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCUN1D3 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV60953014; called by muse, mutect2, varscan2
- DDX25 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99699801; called by muse, mutect2
- DDX27 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100873316; called by muse, mutect2, varscan2
- DEFB119 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as COSV100190693; called by muse, mutect2, varscan2
- DENND2A | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1426914960, COSV99325894; called by muse, varscan2
- DES | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV64659902; called by muse, mutect2, varscan2
- DGAT2 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV99929646; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DGKB | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51777900; called by muse, mutect2, varscan2
- DGKB | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99338134; called by muse, mutect2, varscan2
- DGKG | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV53962083; called by muse, mutect2, varscan2
- DGKI | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1222093392, COSV99933351; called by muse, mutect2, varscan2
- DHX15 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391287, COSV61026742; called by muse, mutect2, varscan2
- DHX15 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100391290; called by muse, mutect2, varscan2
- DIP2A | c.4092C>T p.I1364= | Splice Region (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100595578; called by muse, mutect2, varscan2
- DISP1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52655014; called by muse, mutect2
- DLC1 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.036); catalogued as COSV99362297; called by muse, mutect2, varscan2
- DLEC1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100341847; called by muse, mutect2, varscan2
- DLK2 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99767019; called by muse, mutect2, varscan2
- DNAH1 | c.10814A>C p.E3605A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV101325332; called by muse, mutect2, varscan2
- DNAH10 | c.9052G>A p.D3018N (on ENST00000409039; = p.D2957N on NM_207437.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV101292144, COSV69000109; called by muse, mutect2
- DNAH3 | c.11066C>T p.P3689L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV99766189; called by muse, mutect2, varscan2
- DNAH3 | c.8957G>A p.R2986Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.116); catalogued as rs764888018, COSV99766194; called by muse, mutect2, varscan2
- DNAH5 | c.11528C>T p.S3843L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs78346432, CM065132, COSV54202507; called by muse, mutect2, varscan2
- DNAH5 | c.10712C>T p.P3571L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99447720; called by muse, varscan2
- DNAH5 | c.9905G>A p.R3302K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99447724; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2, varscan2
- DNAH8 | c.12184-1G>C p.X4062_splice | Splice Site (SNP) | VAF 25/112 reads (22%) | catalogued as COSV100544189; called by muse, mutect2, varscan2
- DNER | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as rs767590493, COSV59159659; called by muse, mutect2, varscan2
- DNM3 | c.1197G>A p.R399= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100797972; called by muse, mutect2, varscan2
- DNMT3B | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140860; called by muse, mutect2, varscan2
- DNMT3L | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs201320726, COSV54265764; called by muse, mutect2, varscan2
- DOCK3 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56506346; called by muse, varscan2
- DOCK3 | c.4693G>A p.D1565N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.506); catalogued as rs770897417, COSV99810669; called by muse, mutect2, varscan2
- DOP1B | c.2422del p.Y808Tfs*13 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as COSV101215546; called by mutect2, pindel, varscan2
- DOT1L | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV101288582, COSV101288702; called by muse, mutect2, varscan2
- DPP10 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765952072, COSV59678387; called by muse, mutect2, varscan2
- DPPA2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV101524732; called by muse, mutect2, varscan2
- DPYD | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs749269410, COSV100928645; called by muse, mutect2, varscan2
- DRD5 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58577889; called by muse, mutect2, varscan2
- DRD5 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100431675; called by muse, mutect2, varscan2
- DSC2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs368082152; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DSC3 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV100844565; called by muse, mutect2, varscan2
- DSCAM | c.4563G>A p.W1521* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV101259695; called by muse, varscan2
- DSCAM | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV101259696; called by muse, mutect2, varscan2
- DSG4 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV100355649, COSV57393661; called by muse, mutect2, varscan2
- DTD1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101079773; called by muse, mutect2, varscan2
- DTD1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV101079774, COSV66282928; called by muse, mutect2, varscan2
- DTL | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.813); catalogued as rs531012764, COSV100877176; called by muse, mutect2, varscan2
- DUOX2 | c.3848-1G>A p.X1283_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101199676; called by muse, mutect2, varscan2
- DYNC1I2 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs778704382, COSV99783762; called by muse, mutect2, varscan2
- DYRK1B | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100546532; called by muse, mutect2, varscan2
- DYRK3 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100895656; called by muse, mutect2, varscan2
- ECD | c.1724C>T p.T575I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV100624726; called by muse, mutect2, varscan2
- EFCAB6 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs773603598, COSV53058897; called by muse, mutect2, varscan2
- EFL1 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99186627; called by muse, mutect2, varscan2
- EGF | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54479456; called by muse, mutect2, varscan2
- EIF3E | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs747540507, COSV99623003; called by muse, mutect2, varscan2
- ELAC1 | c.92A>C p.E31A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV99494845; called by muse, mutect2, varscan2
- ELAVL3 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100820723; called by muse, mutect2, varscan2
- ELOA2 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55295225; called by muse, mutect2, varscan2
- ELOVL7 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101415558; called by muse, mutect2, varscan2
- ELP1 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV101010365; called by muse, mutect2, varscan2
- ELSPBP1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs1294881333, COSV100353557; called by muse, mutect2, varscan2
- EMCN | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV56458221; called by muse, mutect2, varscan2
- EMX1 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs902744042, COSV99252453; called by muse, mutect2, varscan2
- ENDOV | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60497788; called by muse, mutect2, varscan2
- ENTPD8 | c.1186G>A p.D396N (on ENST00000371506 / NM_001033113.2; = p.D359N on NM_198585.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.348); catalogued as COSV100395493; called by muse, mutect2, varscan2
- EPG5 | c.5063C>T p.P1688L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99956934; called by muse, mutect2, varscan2
- EPHA3 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs771292552, COSV100344260, COSV100344355; called by muse, mutect2, varscan2
- EPHA3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60696105, COSV60733240; called by muse, mutect2, varscan2
- EPHA6 | c.2203G>A p.E735K (on ENST00000389672 / NM_001080448.3; = p.E127K on NM_173655.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1454303482, COSV67567380; called by muse, mutect2, varscan2
- EPPK1 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV73261510; called by muse, mutect2, varscan2
- EPRS1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV65098819; called by muse, mutect2, varscan2
- ERC2 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV99883034; called by muse, mutect2, varscan2
- ERC2 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99883039; called by muse, mutect2, varscan2
- ERICH3 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.23); catalogued as COSV100443915, COSV58617239; called by muse, mutect2, varscan2
- ERICH5 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100582725; called by muse, mutect2, varscan2
- ESF1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.768); catalogued as rs576513655, COSV99176310; called by muse, mutect2, varscan2
- ESRRG | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs267598381, COSV63152230; called by muse, mutect2, varscan2
- EVPL | c.4916C>T p.S1639L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs763075711, COSV100044291; called by muse, mutect2, varscan2
- F8 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV64271589; called by muse, mutect2, varscan2
- FAAH | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99680014; called by muse, mutect2, varscan2
- FAM131B | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100577912; called by muse, mutect2, varscan2
- FAM135B | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs767926989, COSV52705951; called by muse, mutect2, varscan2
- FAM135B | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52744513; called by muse, mutect2, varscan2
- FAM151A | c.619T>G p.S207A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100156816, COSV56364341; called by muse, mutect2, varscan2
- FAM168A | c.266C>T p.T89I (on ENST00000064778 / NM_001286050.2; = p.T80I on NM_015159.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.076); catalogued as COSV99291698; called by muse, mutect2, varscan2
- FAM171A1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968180; called by muse, mutect2, varscan2
- FAM214A | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV99957810; called by muse, mutect2, varscan2
- FAM217A | c.816G>A p.W272* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV51162224; called by muse, mutect2, varscan2
- FAM217B | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV100674485; called by muse, mutect2, varscan2
- FAM237A | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs750701867, COSV101405578; called by muse, mutect2, varscan2
- FAM47A | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV60497348; called by muse, mutect2, varscan2
- FAM76A | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV50550101; called by muse, mutect2, varscan2
- FAM83E | c.767G>A p.W256* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99572151; called by muse, mutect2, varscan2
- FAM83E | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99613953; called by muse, mutect2, varscan2
- FAT4 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV101272202; called by muse, mutect2, varscan2
- FBF1 | c.2744G>A p.R915Q (on ENST00000586717; = p.R929Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs368877297; called by muse, varscan2
- FBXL6 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs1185143673, COSV100095607; called by muse, mutect2, varscan2
- FBXO15 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99503209; called by muse, mutect2, varscan2
- FCRL3 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1034727140, COSV63840202, COSV63840486; called by muse, mutect2, varscan2
- FERD3L | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762163, COSV51764328; called by muse, mutect2, varscan2
- FGD5 | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53237275, COSV53245932; called by muse, mutect2, varscan2
- FLG | c.7307G>A p.G2436E | Missense Mutation (SNP) | VAF 135/263 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100911377; called by muse, mutect2, varscan2
- FLG | c.5983G>A p.E1995K | Missense Mutation (SNP) | VAF 52/576 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs1315974891, COSV100911378, COSV64247604; called by muse, mutect2
- FLG | c.4198G>A p.G1400R | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100911379; called by muse, mutect2, varscan2
- FLG | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs370748065, COSV100911380; called by muse, mutect2, varscan2
- FLT3 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99608164; called by muse, mutect2, varscan2
- FLVCR1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100875023; called by muse, mutect2, varscan2
- FMN2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV100144331; called by muse, mutect2, varscan2
- FMN2 | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100144332; called by muse, mutect2, varscan2
- FMN2 | c.3945G>A p.W1315* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV60416941; called by muse, mutect2, varscan2
- FMN2 | c.4276G>A p.E1426K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV60424399, COSV60431375; called by muse, mutect2, varscan2
- FMN2 | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV60448982; called by muse, mutect2
- FMO4 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882045; called by muse, mutect2, varscan2
- FMOD | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV100724524; called by muse, mutect2, varscan2
- FNDC1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV51931415; called by muse, mutect2, varscan2
- FNDC1 | c.5203C>T p.P1735S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51940537; called by muse, varscan2
- FOXD4 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1257413109; called by muse, varscan2
- FPGT-TNNI3K | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100436230; called by muse, mutect2, varscan2
- FPR2 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100389219; called by muse, mutect2, varscan2
- FRAS1 | c.7286G>A p.R2429Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs373084707; called by muse, mutect2, varscan2
- FREM2 | c.4894C>T p.P1632S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV54853180; called by muse, mutect2, varscan2
- FREM2 | c.6586G>A p.E2196K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV99748004; called by muse, mutect2, varscan2
- FRMPD2 | c.3887C>T p.S1296F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV100563707; called by mutect2, varscan2
- FSHR | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.072); catalogued as COSV58621462; called by muse, mutect2, varscan2
- FSHR | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV58617732; called by muse, mutect2, varscan2
- FSTL4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.95); PolyPhen benign (0.036); catalogued as COSV99532077; called by muse, mutect2, varscan2
- FUT3 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.138); catalogued as COSV99744460; called by muse, mutect2, varscan2
- FUT9 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100133358; called by muse, mutect2, varscan2
- FYB2 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV58583246; called by muse, mutect2, varscan2
- FYB2 | c.554A>T p.K185M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); catalogued as COSV100599422; called by muse, mutect2, varscan2
- GABRA1 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV50098722, COSV50123051; called by muse, mutect2, varscan2
- GABRA6 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50892822; called by muse, mutect2, varscan2
- GABRB2 | c.1499C>T p.S500F (on ENST00000274547; = p.S462F on NM_000813.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); catalogued as COSV50903913; called by muse, mutect2, varscan2
- GAD2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV99392971; called by muse, mutect2, varscan2
- GAD2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV99392976; called by muse, mutect2
- GALNT13 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs779773642, COSV101223058, COSV67219169; called by muse, mutect2
- GALNT13 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.052); catalogued as rs868521163, COSV67211168; called by muse, varscan2
- GALNT17 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100353266; called by muse, varscan2
- GALNT17 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61169921; called by muse, mutect2, varscan2
- GARNL3 | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59225661; called by muse, mutect2, varscan2
- GCNT3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV68532082; called by muse, mutect2, varscan2
- GDF10 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs201455294; called by muse, mutect2, varscan2
- GFM1 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99962804; called by muse, mutect2, varscan2
- GFOD1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV101015014; called by muse, mutect2, varscan2
- GFRA3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.888); catalogued as COSV99218345; called by muse, mutect2, varscan2
- GFRAL | c.953-1G>A p.X318_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100474912; called by muse, mutect2, varscan2
- GGA3 | c.365C>T p.T122I (on ENST00000537686 / NM_138619.4; = p.T89I on NM_014001.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99822012; called by muse, mutect2, varscan2
- GGN | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.714); catalogued as rs778425172, COSV53057625; called by muse, mutect2, varscan2
- GGPS1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99270391; called by muse, mutect2
- GIGYF2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV65246691, COSV65251823; called by muse, mutect2, varscan2
- GIMAP2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.108); catalogued as COSV99785282; called by muse, mutect2, varscan2
- GLIS1 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.272); catalogued as COSV100389759, COSV100390340; called by muse, mutect2, varscan2
- GLIS3 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1264261637, COSV100173705; called by muse, mutect2, varscan2
- GMEB2 | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99823562; called by muse, mutect2
- GNAO1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.235); catalogued as COSV99340940; called by muse, mutect2, varscan2
- GNAZ | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99320598; called by muse, mutect2, varscan2
- GP1BA | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV56699597; called by muse, mutect2, varscan2
- GPA33 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900986; called by muse, mutect2, varscan2
- GPAM | c.1422C>T p.F474= | Splice Region (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100788152; called by muse, mutect2, varscan2
- GPC1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99882760; called by muse, mutect2
- GPR139 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs746995178, COSV100429782; called by muse, mutect2, varscan2
- GPR156 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV100251267; called by muse, mutect2, varscan2
- GPR55 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV101235789; called by muse, mutect2, varscan2
- GPRASP1 | c.3344A>T p.Y1115F | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100850961, COSV64356508; called by muse, mutect2, varscan2
- GRAP | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as rs1158250940, COSV52414854; called by muse, mutect2
- GRB14 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99813886; called by muse, mutect2, varscan2
- GRIA1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV53616897, COSV99599071; called by muse, mutect2, varscan2
- GRIA1 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53625850; called by muse, mutect2, varscan2
- GRIA1 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53623839, COSV99599077; called by muse, mutect2, varscan2
- GRIA3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs867194096, COSV52068926; called by muse, mutect2, varscan2
- GRIK3 | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV66135735; called by muse, mutect2, varscan2
- GRIN2A | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.19); catalogued as COSV58021908; called by muse, mutect2, varscan2
- GRIN2A | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100408175, COSV58053099; called by muse, mutect2, varscan2
- GRIN2A | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100409270; called by muse, mutect2, varscan2
- GRIN3A | c.1865G>A p.R622K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62458827; called by muse, mutect2, varscan2
- GRIN3A | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62450389; called by muse, mutect2, varscan2
- GRIP1 | c.2695G>A p.E899K (on ENST00000359742 / NM_001379345.1; = p.E847K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV54038440, COSV99668897; called by muse, mutect2, varscan2
- GRIP1 | c.2077C>T p.P693S (on ENST00000359742 / NM_001379345.1; = p.P641S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV99668900; called by muse, mutect2, varscan2
- GRM1 | c.3319C>T p.Q1107* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV99265270; called by muse, mutect2, varscan2
- GRM2 | c.1030T>C p.W344R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99622667; called by muse, mutect2, varscan2
- GRM3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV100862386, COSV64466579; called by muse, varscan2
- GRM3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64468191; called by muse, varscan2
- GRM5 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551183, COSV59603112; called by muse, mutect2, varscan2
- GRM7 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100736069; called by muse, mutect2, varscan2
- GRM8 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV58883196; called by muse, mutect2, varscan2
- GSAP | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV99990086; called by muse, mutect2, varscan2
- GTF2H1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV99786404; called by muse, mutect2, varscan2
- GTF3C2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.024); catalogued as COSV53126253, COSV99272550; called by muse, mutect2, varscan2
- GUCA1A | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50005432; called by muse, mutect2, varscan2
- GUCY2C | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366845328, COSV53795255, COSV99663462; called by muse, mutect2, varscan2
- HAS1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99708318; called by muse, mutect2, varscan2
- HCFC1 | c.5593C>T p.R1865C | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60072013; called by muse, mutect2, varscan2
- HDAC11 | c.737T>A p.L246H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99849836; called by muse, mutect2, varscan2
- HDAC9 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101286630; called by muse, mutect2, varscan2
- HDC | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99983934; called by muse, mutect2, varscan2
- HDGFL3 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100220635; called by muse, mutect2, varscan2
- HEATR3 | c.872T>C p.M291T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1392416015, COSV99589837; called by muse, mutect2, varscan2
- HEATR5B | c.2873C>T p.S958L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1478265371, COSV99248869; called by muse, mutect2, varscan2
- HECTD1 | c.5239G>A p.E1747K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV101237341; called by muse, mutect2, varscan2
- HECW1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1260330810, COSV101223189; called by muse, mutect2, varscan2
- HELT | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100132865; called by mutect2, varscan2
- HEPHL1 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV100243778; called by muse, mutect2, varscan2
- HEY2 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100856348; called by muse, mutect2, varscan2
- HHLA2 | c.1052T>G p.V351G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV100755324, COSV63315778; called by muse, mutect2, varscan2
- HIPK2 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1282903065, COSV100702133; called by muse, mutect2, varscan2
- HIVEP1 | c.3983C>T p.S1328F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV101045025; called by muse, mutect2, varscan2
- HLA-G | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV64407412; called by muse, mutect2
- HNF4A | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.716); catalogued as rs781467980, COSV100290946; called by muse, mutect2, varscan2
- HNF4G | c.967G>A p.E323K (on ENST00000354370 / NM_001330561.2; = p.E370K on NM_004133.5) | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62967143; called by muse, mutect2, varscan2
- HNRNPK | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100698938; called by muse, mutect2, varscan2
- HOXD3 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs867282168, COSV50881074; called by muse, mutect2, varscan2
- HPN | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52885095; called by muse, mutect2, varscan2
- HRG | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs767043667, COSV99214688; called by muse, mutect2, varscan2
- HRNR | c.6421G>A p.G2141R | Missense Mutation (SNP) | VAF 81/2102 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1238479840, COSV64262038; called by muse, mutect2
- HRNR | c.138G>A p.K46= | Splice Region (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100913232; called by muse, mutect2, varscan2
- HSD11B1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV99808022, COSV99808040; called by muse, varscan2
- HSF5 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs868707951, COSV60416173; called by muse, mutect2, varscan2
- HSPG2 | c.8438C>T p.S2813F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV101020577; called by muse, mutect2, varscan2
- HTR1B | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV64051726; called by muse, mutect2, varscan2
- HTR1D | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 25/124 reads (20%) | catalogued as COSV58447734; called by muse, mutect2, varscan2
- HTR1E | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100541034; called by muse, mutect2, varscan2
- HYDIN | c.8150C>T p.S2717F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV59273562; called by mutect2, varscan2
- IARS2 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV100228218; called by muse, mutect2, varscan2
- ICAM2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99856863; called by muse, mutect2, varscan2
- IDUA | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1181224287, COSV99925818; called by muse, mutect2, varscan2
- IFNA16 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); catalogued as COSV101207064; called by muse, mutect2, varscan2
- IFT122 | c.3392-1G>A p.X1131_splice (on ENST00000348417 / NM_052989.3; = p.X1072_splice on NM_018262.4) | Splice Site (SNP) | VAF 27/136 reads (20%) | catalogued as COSV99959058; called by muse, mutect2, varscan2
- IGFBP1 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51874182; called by muse, mutect2, varscan2
- IGFL2 | c.302C>T p.S101F (on ENST00000377693 / NM_001135113.2; = p.S112F on NM_001002915.2) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66617472; called by muse, mutect2, varscan2
- IGKV1D-17 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.08); catalogued as rs377409167; called by muse, mutect2, varscan2
- IGLV2-8 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs560474360; called by muse, mutect2, varscan2
- IL12A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.48); catalogued as COSV99975751; called by muse, mutect2, varscan2
- IL18R1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99294984; called by muse, mutect2, varscan2
- IL21R | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100559987; called by muse, mutect2, varscan2
- IL24 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99686422; called by muse, mutect2, varscan2
- IL2RA | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56923191; called by muse, mutect2, varscan2
- IL9 | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | catalogued as COSV99192420; called by muse, mutect2, varscan2
- INMT | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99184984; called by muse, mutect2, varscan2
- INTS12 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100415789; called by muse, mutect2, varscan2
- IP6K3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs770106812, COSV53389483; called by muse, mutect2, varscan2
- IP6K3 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99539721; called by muse, mutect2, varscan2
- IQUB | c.1431G>A p.W477* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100226951; called by muse, mutect2, varscan2
- IQUB | c.1430G>A p.W477* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV61242725; called by muse, mutect2, varscan2
- IQUB | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100226953; called by muse, mutect2, varscan2
- IRF5 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV99977458, COSV99977604; called by mutect2, varscan2
- ITGA4 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.342); catalogued as COSV101223249; called by muse, mutect2, varscan2
- ITGA4 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV100183448; called by muse, mutect2, varscan2
- ITGB4 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV99563793; called by muse, mutect2, varscan2
- ITPRID2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192229678, COSV57471033; called by muse, mutect2, varscan2
- ITSN2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100743127; called by muse, mutect2, varscan2
- IZUMO1R | c.728C>T p.S243F (on ENST00000440961; = p.S250F on NM_001199206.3) | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1293335375, COSV100126844; called by muse, mutect2, varscan2
- JAKMIP2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54598703; called by muse, mutect2, varscan2
- JAKMIP2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54597715, COSV99507906; called by muse, mutect2, varscan2
- JPH2 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs139139708; called by muse, mutect2, varscan2
- KANK1 | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.551); catalogued as COSV100619627; called by muse, mutect2, varscan2
- KANK4 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV62986852; called by muse, mutect2, varscan2
- KBTBD8 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs530554608, COSV99805498; called by muse, mutect2, varscan2
- KCNA1 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV101230179; called by muse, mutect2, varscan2
- KCNA6 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54975298; called by muse, mutect2, varscan2
- KCNC2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100128562; called by muse, mutect2, varscan2
- KCND2 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.14); catalogued as COSV100474832, COSV104402085; called by muse, mutect2, varscan2
- KCNH5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100526010; called by muse, mutect2, varscan2
- KCNH7 | c.465G>A p.R155= | Splice Region (SNP) | VAF 4/32 reads (13%) | catalogued as COSV59794266; called by muse, mutect2
- KCNJ15 | c.609G>T p.R203S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60811600; called by muse, mutect2, varscan2
- KCNK17 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100950125; called by muse, mutect2, varscan2
- KCNK5 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.298); catalogued as COSV100851802; called by muse, mutect2, varscan2
- KCNQ5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571764; called by muse, mutect2, varscan2
- KCNS2 | c.1430G>C p.R477P | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99750983; called by muse, mutect2, varscan2
- KCNT2 | c.2697+1G>A p.X899_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99652713; called by muse, mutect2
- KCNU1 | c.1911G>A p.M637I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101299090; called by muse, mutect2, varscan2
- KCTD16 | c.660A>T p.E220D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV101568774; called by muse, mutect2, varscan2
- KDM4A | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64960624; called by muse, mutect2, varscan2
- KDM4C | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV101184762; called by muse, mutect2, varscan2
- KDM8 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV99619426; called by muse, mutect2, varscan2
- KIAA0232 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100300594; called by muse, mutect2, varscan2
- KIAA0319 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100985411; called by muse, mutect2, varscan2
- KIAA0408 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as rs1416053083, COSV100846855; called by muse, mutect2, varscan2
- KIAA1143 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99941535; called by muse, mutect2, varscan2
- KIAA1210 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as COSV101274040; called by muse, mutect2, varscan2
- KIF1C | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs747587135, COSV57904715; called by muse, varscan2
- KIF21B | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs760879983, COSV100144240; called by muse, mutect2
- KIF21B | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | catalogued as rs865942025, COSV100144243; called by muse, varscan2
- KIF22 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99360980; called by muse, mutect2, varscan2
- KIF2C | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100945660; called by muse, mutect2, varscan2
- KIR3DL2 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 83/617 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1234707296; called by muse, mutect2, varscan2
- KIR3DL2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as COSV54393733, COSV99551925; called by muse, mutect2, varscan2
- KIR3DX1 | n.662G>A | Splice Region (SNP) | VAF 21/97 reads (22%) | catalogued as COSV99683178; called by muse, mutect2, varscan2
- KIRREL2 | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.998); catalogued as COSV99383814; called by muse, mutect2, varscan2
- KIRREL2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.478); catalogued as rs1338488077, COSV99383816; called by muse, mutect2, varscan2
- KL | c.2935C>T p.R979* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs761487869, COSV101199063; called by muse, mutect2, varscan2
- KLF10 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV99574683; called by muse, mutect2, varscan2
- KLHDC8A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.682); catalogued as COSV100903807; called by muse, mutect2, varscan2
- KLHL1 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376662373, COSV64786648; called by muse, mutect2, varscan2
- KLHL18 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99230722; called by muse, mutect2, varscan2
- KLHL3 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs773712637, COSV100553070; called by muse, mutect2, varscan2
- KLHL32 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV100987214, COSV65112752; called by muse, mutect2, varscan2
- KLRC2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV101122664; called by muse, mutect2, varscan2
- KMT2C | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100070003; called by muse, varscan2
- KMT2C | c.4093-1G>A p.X1365_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100070010, COSV51425225; called by muse, varscan2
- KNL1 | c.3677C>T p.S1226F (on ENST00000346991 / NM_170589.5; = p.S1200F on NM_144508.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV61158795; called by muse, mutect2, varscan2
- KRIT1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100388683; called by muse, mutect2, varscan2
- KRT20 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs150740366, COSV51425102; called by muse, mutect2, varscan2
- KRT32 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV99862965; called by muse, mutect2, varscan2
- KRT7 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100081442; called by muse, mutect2, varscan2
- KRT71 | c.978+1G>A p.X326_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99922075; called by muse, mutect2, varscan2
- KRT80 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); catalogued as COSV100502575; called by muse, mutect2, varscan2
- KRTAP10-11 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100552688; called by muse, mutect2, varscan2
- KRTAP12-1 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV59972420; called by muse, mutect2, varscan2
- KRTDAP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100139253; called by muse, mutect2, varscan2
- KSR2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs765242951, COSV56666019; called by muse, mutect2, varscan2
- KYNU | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99933033; called by muse, mutect2, varscan2
- LAMA1 | c.7982G>A p.S2661N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs902509370, COSV101055771; called by muse, mutect2, varscan2
- LAMA3 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs763917715, COSV58062366; called by muse, mutect2, varscan2
- LAMB4 | c.2438G>A p.G813D | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99223522; called by muse, mutect2, varscan2
- LAMC3 | c.4091C>A p.S1364Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.308); catalogued as COSV100735934, COSV62654115; called by muse, mutect2, varscan2
- LAMP5 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.054); catalogued as rs760241822, COSV99855519; called by muse, mutect2, varscan2
- LBP | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99460655; called by muse, mutect2, varscan2
- LCN2 | c.276G>A p.R92= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52979390; called by muse, mutect2, varscan2
- LDB2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs1161644472, COSV100453272; called by muse, varscan2
- LELP1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs753758248, COSV100907337; called by muse, mutect2, varscan2
- LEMD3 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs746216854, COSV100384250; called by muse, mutect2, varscan2
- LENG8 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV100457309; called by muse, mutect2, varscan2
- LGI3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.333); catalogued as rs866637516, COSV100102964; called by muse, mutect2
- LGMN | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100605767; called by muse, mutect2, varscan2
- LGSN | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV65726500; called by muse, mutect2, varscan2
- LGSN | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101040416; called by muse, mutect2, varscan2
- LIFR | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); catalogued as COSV54693785; called by muse, varscan2
- LIFR | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99663806; called by muse, varscan2
- LILRA4 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759751078, COSV52492084, COSV99393015; called by muse, mutect2, varscan2
- LIM2 | c.462G>A p.G154= (on ENST00000596399 / NM_001161748.2; = p.G196= on NM_030657.4) | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as rs757302099, COSV55742585; called by muse, mutect2, varscan2
- LIPG | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1284769068, COSV99724387; called by muse, mutect2, varscan2
- LIPI | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867097666, COSV60709067; called by muse, mutect2
- LMX1A | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV54215910; called by muse, mutect2
- LPAR4 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868338754, COSV101425097; called by muse, mutect2, varscan2
- LPCAT4 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100148937; called by muse, mutect2, varscan2
- LPO | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV99228624; called by muse, mutect2, varscan2
- LRP1 | c.5722C>T p.P1908S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99675318; called by muse, mutect2, varscan2
- LRP1B | c.12544G>A p.E4182K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs201840295, COSV101254959; called by muse, mutect2, varscan2
- LRPPRC | c.1607C>A p.S536* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99580329; called by muse, mutect2, varscan2
- LRRC8C | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV100968181; called by muse, mutect2, varscan2
- LRRIQ3 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100598627; called by muse, mutect2, varscan2
- LRRK1 | c.5726C>T p.A1909V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV52613988; called by muse, mutect2, varscan2
- LRRK2 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs1350068444, COSV54159202; called by muse, mutect2, varscan2
- LRRN2 | c.2069G>A p.W690* | Nonsense Mutation (SNP) | VAF 60/121 reads (50%) | catalogued as COSV100912808, COSV100912984; called by muse, mutect2, varscan2
- LTBP1 | c.1474G>A p.E492K (on ENST00000404816 / NM_206943.4; = p.E166K on NM_000627.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV63184018, COSV63185189; called by muse, mutect2, varscan2
- LTBP4 | c.1346C>T p.P449L (on ENST00000308370 / NM_001042544.1; = p.P412L on NM_003573.2) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV99183880; called by muse, mutect2, varscan2
- LTN1 | c.3077T>C p.I1026T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100797935; called by muse, mutect2, varscan2
- LUC7L | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs996609757, COSV53457744; called by muse, mutect2, varscan2
- LY75 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99716257; called by muse, mutect2, varscan2
- LY9 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs936287954, COSV99626495; called by muse, mutect2, varscan2
- M6PR | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50003251; called by muse, mutect2, varscan2
- MACC1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); catalogued as COSV100255623; called by muse, mutect2, varscan2
- MACIR | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100174660; called by muse, mutect2, varscan2
- MACO1 | c.1617G>T p.Q539H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100975090; called by muse, mutect2, varscan2
- MAEL | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 55/92 reads (60%) | catalogued as COSV63112319; called by muse, mutect2, varscan2
- MAEL | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.303); catalogued as COSV100901778; called by muse, mutect2, varscan2
- MAGEA12 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs1556833443, COSV63294831; called by muse, mutect2, varscan2
- MAGEB18 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100305278; called by muse, mutect2, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAGEC2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.424); catalogued as COSV55998321, COSV56002040; called by muse, mutect2, varscan2
- MAGI2 | c.773A>C p.D258A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100833934; called by muse, mutect2, varscan2
- MAP2 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV52311183, COSV99559061; called by muse, mutect2, varscan2
- MAP3K21 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as COSV100786250; called by muse, mutect2, varscan2
- MAP4K3 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810207; called by muse, mutect2, varscan2
- MAP7D1 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV60218357; called by muse, mutect2, varscan2
- MARCO | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503354; called by muse, mutect2, varscan2
- MAS1L | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as COSV65808470; called by muse, mutect2, varscan2
- MB21D2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV101165068; called by muse, mutect2, varscan2
- MBIP | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100576754; called by muse, mutect2, varscan2
- MECOM | c.2543G>A p.R848Q (on ENST00000468789 / NM_001105078.4; = p.R1036Q on NM_004991.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs756700169, COSV52959825, COSV52966120; called by muse, mutect2, varscan2
- MED12L | c.6383C>T p.S2128F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99177446; called by muse, mutect2, varscan2
- MEFV | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54820486; called by muse, mutect2, varscan2
- MEGF6 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.057); catalogued as COSV100742122; called by muse, mutect2, varscan2
- MEIOC | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370251992, COSV100740173; called by mutect2, varscan2
- MERTK | c.2022G>A p.M674I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99774411; called by muse, mutect2, varscan2
- MET | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1249371062, COSV100577135; called by muse, mutect2, varscan2
- MFSD1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99963723; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MGAM | c.3949G>A p.D1317N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV101527436, COSV72074703; called by muse, mutect2
- MGAT3 | c.159T>G p.N53K | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100361822; called by muse, mutect2, varscan2
- MGRN1 | c.1016T>A p.V339E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99273971; called by muse, mutect2, varscan2
- MICAL3 | c.3310C>T p.Q1104* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101490842; called by muse, mutect2
- MICU3 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771460585, COSV100536226; called by muse, mutect2, varscan2
- MINDY1 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.086); catalogued as COSV56500389; called by muse, mutect2, varscan2
- MIOX | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761767637, COSV99326773; called by muse, mutect2, varscan2
- MIOX | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99326778; called by muse, mutect2, varscan2
- MIP | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV99234159; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by muse, mutect2, varscan2
- MLC1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.124); catalogued as COSV100286285; called by muse, mutect2, varscan2
- MLLT3 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100580856; called by muse, mutect2, varscan2
- MMP2 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99527616; called by muse, mutect2, varscan2
- MMP28 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.212); catalogued as rs1314466913; called by muse, mutect2
- MNDA | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161457689, COSV63741515, COSV63742101; called by muse, mutect2, varscan2
- MNDA | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV100933296; called by muse, mutect2, varscan2
- MOK | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV99513074; called by muse, mutect2, varscan2
- MORC1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs549951203, COSV51714451; called by muse, mutect2
- MORC2 | c.1636C>T p.P546S (on ENST00000397641 / NM_001303256.3; = p.P484S on NM_014941.3) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53198450; called by muse, mutect2, varscan2
- MORC3 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV101247724; called by muse, mutect2, varscan2
- MOV10L1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs762299641, COSV99433434; called by muse, mutect2, varscan2
- MPZL1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100850336; called by muse, mutect2, varscan2
- MROH2B | c.4551G>A p.W1517* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101270617, COSV68189096; called by muse, mutect2
- MROH2B | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68188956; called by muse, mutect2, varscan2
- MROH7 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV100988549; called by muse, mutect2, varscan2
- MRPS5 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV99720766; called by muse, mutect2, varscan2
- MS4A14 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs1288438995, COSV100280252; called by muse, mutect2, varscan2
- MTHFR | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV57171296; called by muse, mutect2, varscan2
- MUC16 | c.41413G>A p.E13805K | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.915); catalogued as COSV66690158; called by muse, mutect2, varscan2
- MUC16 | c.22906C>T p.L7636F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV101199274; called by muse, mutect2, varscan2
- MUC16 | c.16517C>T p.T5506I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs766752080, COSV101199277, COSV67476936; called by muse, mutect2, varscan2
- MUC16 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67445914; called by muse, mutect2, varscan2
- MUC17 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100072583; called by muse, mutect2, varscan2
- MUC4 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.02); catalogued as COSV100640229; called by muse, mutect2, varscan2
- MVB12B | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100752741; called by muse, mutect2, varscan2
- MX1 | c.927C>T p.F309= | Splice Region (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99912546; called by muse, mutect2, varscan2
- MXRA5 | c.4070C>T p.S1357F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99476369; called by muse, mutect2, varscan2
- MYCBPAP | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99276825; called by muse, mutect2, varscan2
- MYH1 | c.5608G>A p.D1870N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1262966974, COSV99875438; called by muse, mutect2, varscan2
- MYH2 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99819757; called by muse, mutect2, varscan2
- MYLK3 | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101189091; called by muse, mutect2, varscan2
- MYLK4 | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV99193747; called by muse, mutect2, varscan2
- MYO15A | c.4390G>A p.V1464M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99231998, COSV99234461; called by muse, mutect2, varscan2
- MYO18B | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100123167; called by muse, varscan2
- MYO1B | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as rs1257881728, COSV100268890; called by muse, mutect2, varscan2
- MYO1D | c.1736T>A p.L579H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554007; called by muse, mutect2, varscan2
- MYO1F | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866917226, COSV100596536; called by muse, mutect2, varscan2
- MYO3A | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56322905; called by muse, mutect2, varscan2
- MYO3A | c.2717G>A p.G906D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV99779102; called by muse, mutect2, varscan2
- MYO3A | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764099857, COSV56352356, COSV99075848; called by muse, mutect2, varscan2
- MYOCD | c.1197C>G p.D399E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100590490; called by muse, mutect2, varscan2
- MYPN | c.3710A>G p.K1237R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.046); catalogued as COSV100589791; called by muse, mutect2, varscan2
- MYRIP | c.2350C>T p.Q784* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100218763; called by muse, mutect2, varscan2
- N4BP2 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as COSV99788453; called by muse, mutect2, varscan2
- NACA2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs372064190, COSV71713087; called by muse, mutect2, varscan2
- NAGK | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV99730545; called by muse, mutect2, varscan2
- NALCN | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99214076; called by muse, mutect2, varscan2
- NBR1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100357765, COSV57832321; called by muse, mutect2, varscan2
- NCAM1 | c.1343G>A p.W448* (on ENST00000316851 / NM_181351.5; = p.W438* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100377080, COSV100377338; called by muse, mutect2, varscan2
- NCAM1 | c.1344G>A p.W448* (on ENST00000316851 / NM_181351.5; = p.W438* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs1555117407, COSV100377367; called by muse, mutect2, varscan2
- NCAN | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.752); catalogued as rs760892655, COSV99386953; called by muse, varscan2
- NCKAP5 | c.5305C>T p.L1769F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV100491119; called by muse, mutect2, varscan2
- NCKAP5 | c.4150G>A p.G1384R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100491121; called by muse, mutect2, varscan2
- NCKAP5 | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100491123; called by muse, mutect2, varscan2
- NCOR2 | c.5576C>T p.P1859L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100657123; called by muse, mutect2
- NDE1 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as rs747020521, CM135672, COSV100706896; called by muse, mutect2, varscan2
- NDST4 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99996063, COSV99997499; called by muse, mutect2, varscan2
- NEDD4L | c.2167C>T p.H723Y (on ENST00000400345 / NM_001144967.3; = p.H703Y on NM_015277.6) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99894280; called by muse, mutect2, varscan2
- NEK5 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100839182, COSV62880189; called by muse, mutect2, varscan2
- NETO1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs267605254, COSV55001194; called by muse, mutect2, varscan2
- NETO2 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs1319831376, COSV100292395; called by muse, mutect2, varscan2
- NEU1 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs751458617, CM040099, CM113390, COSV99998821; called by muse, mutect2, varscan2
1,547 further variants in this file (686 protein-altering or splice-affecting, 798 silent, 63 other) are not listed here.
